MMRF case MMRF_2137 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5206e3f4-95f1-45c7-81bb-e93fbbeac5e3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,066 days); ISS stage: I; Days to last known disease status: 886 days (2.4 years); Days to last follow up: 886 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 157 days; Days to treatment end: 157 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 467 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -37 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 4.38 g/L; Immunoglobulin A 3.73 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.05 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 7.4 g/dL; Glucose 6.38 mmol/L; C-Reactive Protein 0.359 mg/dL.
- Day 64 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.5 mg/dL; Immunoglobulin G 3.59 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.22 g/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 3.52 mmol/L.
- Day 122 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 3.4 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.77 mmol/L.
- Day 184 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.08 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 270: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 1.76 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.47 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 361: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.09 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 6.38 mmol/L.
- Day 452 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 1.66 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 51 g/L; Total Protein 7.4 g/dL; Glucose 6.38 mmol/L.
- Day 585: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 8.67 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.72 mmol/L.
- Day 690 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.03 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 800 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.95 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Total Protein 7 g/dL; Glucose 7.76 mmol/L.
- Day 886 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 2.89 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 7.26 mmol/L.

Other clinical attributes
- Day -37: Weight: 64 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2137_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -37 days.
- Sample MMRF_2137_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -37 days.
